Surgical pathology report (de-identified scan), TCGA case TCGA-TM-A84F, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site The University of New South Wales, specimen TCGA-TM-A84F-01A (Primary Tumor).

Patient Results

Anatomical Pathology results performed since

Final

SEX : M
D.O.B.

LAB. NO. :
DOCTOR :
WARD :
REQUEST DATE :
DATE RECEIVED :
CONSULTANT :

COPY TO:
SPECIMEN:
Right frontal lobe.
CLINICAL :
Right frontal lobe tumour.
MACROSCOPIC:

A discoid piece of brain 75 x 65 x 16mm, including cortex and white matter. The cerebral surface has a bulging appearance due to pronounced swelling of several adjacent gyri causing sulcal compression, over an area of approximately 40 x 30mm. Serial sections show marked cortical thickening in areas measuring up to 8mm in thickness. The underlying white may also be expanded but difficult to judge and within this region there is loss of cortico-medullary demarcation. Within the grey matter is a 2mm cystic space filled with altered blood (looks traumatic). The adjacent brain parenchyma appears within normal limits. Brain surface and 2 sections (cut face) photographed. Tissue submitted for EM and cytogenetics.

BLOCK KEY:
1-8:lesional brain, 9,10:cortical blood clot, 11-14:normal appearing brain parenchyma

MICROSCOPIC:
Representative sections of lesional brain show grey and white matter with a diffusely infiltrating glioma of variable cellularity. The neoplastic cells are set within a fibrillary and focally microcystic stroma and display a range of morphological features. The predominant cell type has intermediate sized, round to oval and also spindly nuclei with a vesicular chromatin pattern. There is mild pleomorphism and occasional prominent nucleoli are seen. Some cells have perinuclear clearing resembling oligodendrocytes. Within other areas of the tumour are cells with larger irregular oval nuclei which are favoured to be astrocytic. Focal zones with a spindled morphology are also present. Some areas contain moderate numbers of gemistocytic cells, including some mini-gemistocytes. Mitotic activity is variable and some areas do show moderate activity. The MIB-1 proliferation index remains low, with approximately 5% of cells showing positive staining. There is no evidence of necrosis. A moderate lymphoplasmacytic infiltrate is seen within the Virchow-Robin space. FISH studies pending.

CONCLUSION:
Right frontal lobe tumour (preliminary report) : Preliminary histopathology favours a WHO Grade III astrocytoma not excluding the possibility of a mixed oligoastrocytoma. FISH studies for 1p and 19q deletions and EGFR amplification are being performed and results will be issued in a supplementary report.

REGISTRAR: PATHOLOGIST:
DOCTOR REVIEWING:

DATED:
ELECTRONICALLY VALIDATED:

ICD-O-3

Astrocytoma, grade II 9401/5
Site: Brain, supratentorial C71.0
path R Brain, frontal lobe C71.1
Spd 10/30/13

Source: NCI Genomic Data Commons file 63e67366-56b3-4f8c-be6f-e76b11931d94 (TCGA-TM-A84F.5142804B-6A45-44E9-99A1-711C9C14F576.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).